CCDI case PBBRNY — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cdce04a0-19ff-4677-903b-d3863d23ac10

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Choroid plexus papilloma, NOS: ICD-O-3 morphology code: 9390/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.9 years (5,801 days).

Biospecimens (4 samples)
- Sample 0DGSR5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DGSR8, 0DGSRG (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DGWOK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
